Surgical pathology report (de-identified scan), TCGA case TCGA-A6-5662, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-5662-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Splenic flexure please send for K-ras

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left colon cancer.

GROSS DESCRIPTION

Received fresh labeled "splenic flexure" is a previously unopened, 15 cm. segment of colon surfaced by smooth, glistening tan-pink serosa with a moderate amount of attached mesocolon. The undesignated margins average 4.6 cm. in circumference. Central palpable mesenteric mass is noted and the overlying surface is inked blue. On opening, there is a central, 3.8 x 3.4 cm. rubbery tan white-pink tumor mass which is equidistantly located 7.5 cm from each of the undesignated margins. On sectioning, the tumor has a maximal thickness of 2 cm. grossly extending into the muscularis to within 0.4 cm. of the inked free radial serosal surface. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. No additional mass lesion or abnormality is identified. The aforementioned mesenteric mass measures 2.7 cm in greatest

dimension

with glistening tan-white cut surfaces and appears contiguous with the aforementioned mucosal tumor, spanning an overall depth of 3.2 cm. and focally extending to within 0.1 cm. of the inked free

radial

serosal surface (see contiguous sections blocks 5 and 6). The remaining mucosa is unremarkable glistening tan pink with regular folds and the wall averages 0.5 cm. in thickness. A few soft to rubbery tan white-pink tissues in keeping with lymph nodes

measuring

up to 2 cm. in greatest dimension are recovered from the attached mesocolon. Representative sections are submitted in 15 blocks as labeled. RS-15.

BLOCK SUMMARY: 1 - Proximal and distal margins; 2-6 tumor full thickness to inked free radial serosal surface (cassettes 5 and 6 represent tumor to mesenteric mass with point of continuity inked green); 7 - random colon; 8 - three whole lymph nodes; 9-12 - one bisected lymph node per cassette; 13-15 - additional mesocolon (in lieu of minimal number of nodes normally required).

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Moderate to poorly differentiated
Primary tumor (pT): Extends to the muscularis propria and into pericolic tissue (pT3)
Proximal margin: Uninvolved
Distal margin: Uninvolved
Circumferential (radial) margin: Close
Vascular invasion: Present
Regional lymph nodes (pN): Metastatic carcinoma is present in 7 of 13 pericolic lymph nodes (pN2).
Non-lymph node pericolic tumor: Extensive
Distant metastasis (pM): Could not be evaluated by this specimen (pMX)
Other findings: None

5

DIAGNOSIS

Colon, splenic flexure, resection:
Adenocarcinoma, moderate to poorly differentiated, depth of invasion through muscularis propria.
Surgical margins uninvolved.
Metastatic carcinoma present in 7 of 13 lymph nodes [REDACTED]

[REDACTED]

DIAG

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 9e9dfd28-baad-47fc-be75-8ac30feba770 (TCGA-A6-5662.79935EC7-C03D-4DBF-97A6-C97DA85AF6D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).